Somatic mutation profile of tumor specimen TCGA-DX-A6BF-01A (aliquot TCGA-DX-A6BF-01A-11D-A307-09) from TCGA case TCGA-DX-A6BF, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 82.3 years (30,071 days).
Specimen TCGA-DX-A6BF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c27da9d9-44c8-4f4f-a24e-784024040e98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6BF-10A (Blood Derived Normal), aliquot TCGA-DX-A6BF-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c52f2b02-c885-4171-a9db-b061b258d25b

The open-access MAF lists 75 somatic variants for this specimen: 59 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, 3'Flank 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NR1H4 | c.556C>T p.R186* (on ENST00000551379 / NM_001206993.2; = p.R176* on NM_005123.4) | Nonsense Mutation (SNP) | VAF 672/818 reads (82%) | catalogued as rs113090017, CM114655, COSV51854643; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.2797C>A p.P933T | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100068507; called by muse, mutect2, varscan2
- ADGRE5 | c.478+2T>C p.X160_splice | Splice Site (SNP) | VAF 54/205 reads (26%) | catalogued as COSV99662928; called by muse, varscan2
- ALK | c.2356-1G>C p.X786_splice | Splice Site (SNP) | VAF 48/152 reads (32%) | catalogued as rs1379529516, COSV101202041; called by muse, mutect2, varscan2
- ANKZF1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs375422658; called by muse, mutect2, varscan2
- ATXN7 | c.1735C>T p.H579Y | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs1320309275, COSV99894475; called by muse, mutect2, varscan2
- CADPS2 | c.139C>A p.R47S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV100462947; called by muse, mutect2, varscan2
- CCDC141 | c.2390A>G p.E797G | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99836861; called by muse, mutect2, varscan2
- CDH9 | c.12C>A p.Y4* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV50251677, COSV99144966; called by muse, mutect2, varscan2
- CDK14 | c.141G>A p.M47I (on ENST00000380050 / NM_001287135.2; = p.M29I on NM_012395.3) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.48); catalogued as rs1375098549, COSV56057227; called by muse, mutect2, varscan2
- CFAP54 | c.4847T>G p.I1616S | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV100733177; called by muse, mutect2, varscan2
- CH25H | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100897355; called by muse, mutect2, varscan2
- DNAJB11 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV99408636; called by muse, mutect2, varscan2
- DPY19L2 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 1767/3100 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs754869560, COSV100116779; called by muse, mutect2, varscan2
- FADS1 | c.1464G>C p.K488N | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100650260; called by muse, varscan2
- FAM71A | c.413A>T p.Q138L | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99674617; called by muse, mutect2, varscan2
- GPR156 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV100251387; called by muse, mutect2, varscan2
- HDGFL3 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100220747; called by muse, mutect2, varscan2
- IL27RA | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as rs1252562514, COSV99652173; called by muse, mutect2, varscan2
- ING4 | c.739A>T p.K247* (on ENST00000396807 / NM_001127582.2; = p.K246* on NM_016162.4) | Nonsense Mutation (SNP) | VAF 97/280 reads (35%) | catalogued as COSV99976135; called by muse, mutect2, varscan2
- ITPR2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 61/173 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV54382835, COSV99659331; called by muse, mutect2, varscan2
- KIAA1217 | c.5330G>A p.R1777H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs900550683, COSV56814935; called by muse, mutect2, varscan2
- KLHL32 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV65113589; called by muse, mutect2, varscan2
- KRR1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 264/977 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV57517519; called by muse, mutect2, varscan2
- LILRA5 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.395); catalogued as COSV100006937; called by muse, mutect2, varscan2
- MGAT4C | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 34/748 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1271898429, COSV100152970; called by muse, mutect2
- MMP7 | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV99497069; called by muse, mutect2, varscan2
- MON2 | c.2174G>T p.G725V | Missense Mutation (SNP) | VAF 116/861 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as COSV99742618; called by muse, mutect2, varscan2
- MUC16 | c.30790A>G p.T10264A | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101199990; called by muse, mutect2, varscan2
- MUC16 | c.18601A>C p.N6201H | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.353); catalogued as COSV101199991; called by muse, mutect2, varscan2
- MYB | c.791C>A p.A264E | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.698); catalogued as COSV100214866; called by muse, mutect2, varscan2
- NAV3 | c.3878C>A p.S1293Y | Missense Mutation (SNP) | VAF 185/1641 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99886611, COSV99891195; called by muse, mutect2, varscan2
- NOTCH3 | c.6947A>G p.K2316R | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99657276; called by muse, mutect2
- OR1C1 | c.521T>C p.I174T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1425068953, COSV101376228; called by muse, mutect2, varscan2
- PANK1 | c.1742A>G p.Y581C (on ENST00000307534 / NM_148977.2; = p.Y297C on NM_138316.4) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100285657; called by muse, mutect2, varscan2
- PBRM1 | c.2227T>A p.S743T | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99968845; called by muse, mutect2, varscan2
- PCDHGC3 | c.26G>C p.G9A | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.079); catalogued as COSV99340241; called by muse, mutect2, varscan2
- PLEKHA6 | c.2287G>C p.A763P | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.307); catalogued as COSV99692083; called by muse, mutect2
- RAB3IP | c.712C>G p.L238V (on ENST00000550536 / NM_175623.4; = p.L222V on NM_022456.5) | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV99923243; called by muse, mutect2
- RNASE10 | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100116140; called by muse, mutect2, varscan2
- RNF31 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs374504041; called by muse, mutect2, varscan2
- SIRT7 | c.485A>G p.Q162R | Missense Mutation (SNP) | VAF 74/135 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100155549; called by muse, mutect2, varscan2
- SLC22A10 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs200183991; called by muse, mutect2, varscan2
- SLC35F4 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV100333870, COSV60262620; called by muse, mutect2, varscan2
- SOX3 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100983707; called by muse, mutect2
- SOX3 | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV100983709; called by muse, mutect2
- SPATA17 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs200145412, COSV65120787; called by muse, mutect2, varscan2
- THBS1 | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764234776, COSV52951936; called by muse, mutect2, varscan2
- TMC2 | c.1571T>G p.L524R | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100727616; called by muse, mutect2, varscan2
- TMEM120A | c.937C>G p.P313A | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.41); catalogued as COSV100115623; called by muse, mutect2, varscan2
- TOX | c.352A>T p.I118F | Missense Mutation (SNP) | VAF 99/262 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV100812744; called by muse, mutect2, varscan2
- TRIM42 | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99648377; called by muse, mutect2, varscan2
- TTN | c.63602T>C p.I21201T (on ENST00000591111; = p.I13777T on NM_003319.4) | Missense Mutation (SNP) | VAF 53/160 reads (33%) | PolyPhen probably damaging (0.996); catalogued as rs368301580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VEGFC | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 111/278 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99709846; called by muse, mutect2, varscan2
- WNK4 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99519431; called by muse, mutect2, varscan2
- ZMAT4 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.484); catalogued as COSV99910022; called by muse, mutect2, varscan2
- ATP23 | c.32_41del p.G11Efs*44 | Frame Shift Del (DEL) | VAF 65/387 reads (17%) | called by mutect2, pindel, varscan2
- MCM10 | c.456dup p.E153Rfs*9 | Frame Shift Ins (INS) | VAF 27/88 reads (31%) | called by mutect2, pindel, varscan2
- UGT1A10 | c.569del p.V190Afs*6 | Frame Shift Del (DEL) | VAF 45/166 reads (27%) | called by mutect2, pindel, varscan2
- AVIL | c.621G>C p.V207= | Silent (SNP) | VAF 478/564 reads (85%) | catalogued as COSV99142389; called by muse, mutect2, varscan2
- CAPS2 | c.1477C>T p.L493= | Silent (SNP) | VAF 460/2196 reads (21%) | catalogued as COSV100157778; called by muse, mutect2, varscan2
- DEFB134 | c.30T>C p.F10= | Silent (SNP) | VAF 51/315 reads (16%) | catalogued as rs759357041, COSV101198490; called by muse, mutect2, varscan2
- FMNL3 | c.807C>A p.V269= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as COSV99526345; called by muse, mutect2, varscan2
- GAK | c.2361C>T p.D787= | Silent (SNP) | VAF 90/198 reads (45%) | catalogued as rs112202640; called by muse, mutect2, varscan2
- GBE1 | c.1968A>G p.E656= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as COSV101450154; called by muse, mutect2, varscan2
- GRIA1 | c.1266C>G p.L422= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV99599918; called by muse, mutect2, varscan2
- HELB | c.2898G>T p.P966= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99921923; called by muse, mutect2, varscan2
- KIAA1210 | c.4029G>A p.Q1343= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV68178195; called by muse, mutect2, varscan2
- KRT83 | c.1383C>T p.P461= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs1254550964, COSV99531642; called by muse, mutect2, varscan2
- MEGF6 | c.2223G>T p.S741= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs200439973, COSV99620402; called by muse, mutect2, varscan2
- OR13C5 | c.817T>C p.L273= | Silent (SNP) | VAF 43/279 reads (15%) | catalogued as rs141268591, COSV66164122; called by muse, mutect2, varscan2
- PTPRR | c.1395G>T p.T465= | Silent (SNP) | VAF 27/584 reads (5%) | catalogued as rs565130853, COSV51725656, COSV51743207; called by muse, mutect2
- TRIP12 | c.1419G>A p.L473= | Silent (SNP) | VAF 39/58 reads (67%) | catalogued as COSV52267234, COSV99390299; called by muse, mutect2, varscan2
- TUBB8 | c.6G>A p.R2= | Silent (SNP) | VAF 77/199 reads (39%) | catalogued as rs1554739063, COSV100226062; called by muse, mutect2, varscan2
- ACTRT3 | chr3:169764987 G>A | 3'Flank (SNP) | VAF 62/287 reads (22%) | catalogued as rs1324875775; called by muse, mutect2, varscan2
